Gene-level copy-number profile of tumor specimen ALCH-B258-TTP1-A from ALCHEMIST case ALCH-B258, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.6 years (19,590 days).
Specimen ALCH-B258-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c83bf5af-ef65-457b-b15c-e897e3d79963.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B258-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/37974d11-a54c-4457-9662-5ae46fbe7f7d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 21,357; copy number 2: 35,906; copy number 3: 617; copy number 4: 176; copy number 5: 47; copy number 6: 179; copy number 7: 96; copy number 8: 3; copy number 18: 1; copy number 20: 1; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:218,990,189–219,001,708, 2 genes: CRYBA2, MIR375.
- chr16:89,948,697–89,968,060, 1 gene: DEF8.
- chr17:22,221,221–22,266,392, 2 genes: FTLP13, LINC02002.
- chr17:31,465,543–31,465,832, 1 gene (within-gene range 0–2): RN7SL79P.
- chr17:78,174,091–78,187,233, 1 gene: TK1.
- chr19:1,103,926–1,106,791, 1 gene: GPX4.
- chr22:25,455,646–25,455,711, 1 gene (within-gene range 0–1): MIR6817.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 328 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:137,518,134–142,448,062, 96 genes, copy number 6 (broad region; genes not listed).
- chr3:147,590,996–149,736,714, 42 genes, copy number 7 (within-gene range 4–7): NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046, AC069410.1, RPL38P1, AGTR1, CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P.
- chr3:149,656,999–149,661,364, 1 gene, copy number 7 (within-gene range 4–7): WWTR1-AS1.
- chr7:54,419,444–56,340,337, 57 genes, copy number 6: SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P.
- chr7:74,773,962–74,851,551, 2 genes, copy number 8–20: NCF1, GTF2IRD2.
- chr8:50,859,530–50,860,062, 1 gene, copy number 6: AC087272.1.
- chr8:53,493,523–53,959,303, 10 genes, copy number 6: AC022034.1, AC022034.4, AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P.
- chr8:80,241,389–81,924,348, 52 genes, copy number 5–7: MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:82,098,451–82,160,577, 1 gene, copy number 5: LINC02839.
- chr8:120,059,780–120,542,133, 3 genes, copy number 6 (within-gene range 3–6): COL14A1, MRPL13, MTBP.
- chr8:123,497,889–123,815,452, 7 genes, copy number 6: FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1.
- chr8:125,998,994–128,564,679, 37 genes, copy number 5: AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr11:1,157,953–1,201,138, 1 gene, copy number 8: MUC5AC.
- chr14:105,664,633–105,669,843, 1 gene, copy number 8 (within-gene range 2–8): IGHGP.
- chr16:1,064,093–1,113,399, 6 genes, copy number 7: SSTR5-AS1, AC009041.2, SSTR5, C1QTNF8, AL031713.1, AL031598.1.
- chr16:89,906,157–89,920,973, 2 genes, copy number 5–7 (within-gene range 1–7): AC092143.3, MC1R.
- chr19:397,589–409,147, 2 genes, copy number 5–18: AC010641.1, C2CD4C.
- chr19:463,346–474,983, 1 gene, copy number 43: ODF3L2.
- chr19:1,065,923–1,095,380, 2 genes, copy number 5–6: ARHGAP45, POLR2E.
- chr22:20,148,416–20,151,055, 1 gene, copy number 6: CCDC188.
- chr22:21,103,016–21,128,063, 3 genes, copy number 6: BCRP2, AP000550.1, POM121L7P.

Autosomal genes at a single copy (total copy number 1): 21,324. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
